Somatic mutation profile of tumor specimen MP2PRT-PASUMX-TMP1-A (aliquot MP2PRT-PASUMX-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASUMX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,162 days).
Specimen MP2PRT-PASUMX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e02fe0fd-129f-439d-96d4-3882bd9379fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUMX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUMX-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d687b4-1072-4754-9c84-474d402e71c9

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 26, Silent 4, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 37/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 106/314 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALLC | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs745607491, COSV52997998; called by muse, mutect2, varscan2
- CAMSAP3 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 48/502 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.353); catalogued as rs1555761891; called by muse, mutect2
- CCN3 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52384398; called by muse, mutect2
- CHD4 | c.2884C>T p.R962C (on ENST00000357008 / NM_001363606.2; = p.R975C on NM_001273.5) | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58902074; called by muse, mutect2, varscan2
- CYP1B1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 186/523 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs9341250; called by muse, mutect2, varscan2
- DNAJC11 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 137/281 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs759127830, COSV53786111; called by muse, mutect2, varscan2
- GLRB | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV52417126; called by muse, mutect2, varscan2
- GRIA2 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV52407089; called by muse, mutect2
- KCNH3 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 210/408 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV57790664; called by muse, mutect2, varscan2
- LATS2 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 191/404 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755932669; called by muse, mutect2, varscan2
- MAPK4 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 241/510 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as rs764772500, COSV68541047, COSV68543116; called by muse, mutect2, varscan2
- RGS13 | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs774539605; called by muse, mutect2, varscan2
- SCRIB | c.4807G>A p.A1603T | Missense Mutation (SNP) | VAF 304/632 reads (48%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.005); catalogued as rs782744068; called by muse, mutect2, varscan2
- SLC40A1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 196/398 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs752593581, COSV53725387; called by muse, mutect2, varscan2
- TCTE1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 72/538 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs751205346; called by muse, mutect2
- WIPF1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV55810997; called by muse, mutect2, varscan2
- ACKR3 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 199/504 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARFGEF2 | c.3409G>A p.V1137M | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ATP7A | c.2225A>C p.K742T | Missense Mutation (SNP) | VAF 35/519 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.419); called by muse, mutect2
- CTCF | c.410_432del p.A137Gfs*7 | Frame Shift Del (DEL) | VAF 28/288 reads (10%) | called by mutect2, pindel
- DLL3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 121/364 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FIGNL2 | c.1756_1757insCCGC p.L586Pfs*49 | Frame Shift Ins (INS) | VAF 184/555 reads (33%) | called by mutect2, pindel, varscan2
- IGHV1-69 | chr14:106714679 GTGTCTCTCGCACAGT>TCCGCACAGGA | Missense Mutation (DEL) | VAF 93/105 reads (89%) | called by pindel, varscan2*
- MXRA5 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 171/447 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDSS1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 191/479 reads (40%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT7 | c.67C>A p.H23N | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP14 | c.249C>T p.F83= | Silent (SNP) | VAF 19/355 reads (5%) | catalogued as rs776761326, COSV99692970; called by muse, mutect2
- DAB1 | c.1086C>T p.V362= (on ENST00000371231; = p.V329= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 177/446 reads (40%) | catalogued as rs773042070, COSV64691845, COSV64693307; called by muse, varscan2
- NAV3 | c.3984G>A p.S1328= | Silent (SNP) | VAF 190/399 reads (48%) | catalogued as rs773932556, COSV99894282; called by muse, mutect2, varscan2
- PROP1 | c.198G>A p.P66= | Silent (SNP) | VAF 321/655 reads (49%) | catalogued as rs769315766, COSV57644591; called by muse, mutect2, varscan2
